Somatic mutation profile of tumor specimen TCGA-90-7964-01A (aliquot TCGA-90-7964-01A-21D-2184-08) from TCGA case TCGA-90-7964, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.2 years (25,646 days).
Specimen TCGA-90-7964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ea2bb74-026b-4dd1-ae2a-65ab89248ff4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-7964-10A (Blood Derived Normal), aliquot TCGA-90-7964-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b651ee04-e971-48bf-8501-68edf11e92c0

The open-access MAF lists 524 somatic variants for this specimen: 388 protein-altering or splice-affecting, 121 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 343, Silent 121, Nonsense Mutation 18, Frame Shift Del 13, Frame Shift Ins 6, Splice Region 4, Splice Site 3, Intron 3, 5'UTR 3, RNA 3, 3'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs745931683, COSV55939775, COSV99711066; called by muse, mutect2, varscan2
- ABCC11 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV100751042; called by muse, mutect2, varscan2
- ACAN | c.6224C>A p.T2075K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as rs1321885900, COSV100718984; called by muse, mutect2, varscan2
- ACAT1 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV99759365; called by muse, mutect2, varscan2
- ACP5 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54535500, COSV54537641; called by muse, mutect2, varscan2
- ADAMTS18 | c.1361G>C p.R454T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV51409003, COSV99273815; called by muse, mutect2, varscan2
- ADAMTS5 | c.1956G>C p.W652C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99538158; called by muse, mutect2, varscan2
- ADH1A | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as COSV99265938; called by muse, mutect2, varscan2
- AFF3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100419836, COSV57878789; called by muse, mutect2, varscan2
- AGAP3 | c.1376G>T p.G459V (on ENST00000622464; = p.G495V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV101257354; called by muse, mutect2
- AL592490.1 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101308261; called by muse, mutect2, varscan2
- ALPK2 | c.6478G>A p.A2160T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100864723; called by muse, mutect2, varscan2
- AMPH | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV100343234; called by muse, mutect2, varscan2
- ANK3 | c.8443G>A p.E2815K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99781723; called by muse, mutect2, varscan2
- APOB | c.9872G>A p.R3291H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs747787527, COSV51946964; called by muse, mutect2, varscan2
- APOB | c.9194C>T p.T3065I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.51); catalogued as COSV99267277; called by muse, mutect2, varscan2
- ARFGEF1 | c.3754A>G p.I1252V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99144046; called by muse, mutect2, varscan2
- ASTN2 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100529649, COSV57755805; called by muse, mutect2, varscan2
- ATG4D | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100470366; called by muse, varscan2
- ATN1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV63112840; called by muse, mutect2, varscan2
- ATXN7L1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100596959; called by muse, mutect2, varscan2
- B3GNT7 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99805994; called by muse, mutect2
- BAMBI | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.121); catalogued as COSV100977532; called by muse, mutect2, varscan2
- BBX | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV100362127; called by muse, mutect2, varscan2
- BEST3 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99876336; called by muse, mutect2, varscan2
- BPI | c.437C>A p.A146D (on ENST00000262865; = p.A142D on NM_001725.3) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53408904, COSV99480885; called by muse, mutect2, varscan2
- BPIFB2 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99401603; called by muse, mutect2, varscan2
- BPIFB4 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100971628; called by muse, mutect2, varscan2
- BRINP2 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100838288; called by muse, mutect2, varscan2
- C11orf24 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100422461, COSV100422672; called by muse, mutect2, varscan2
- CARMIL1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100278605; called by muse, mutect2, varscan2
- CCDC62 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99457550; called by muse, mutect2, varscan2
- CD163 | c.3446C>T p.T1149I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.353); catalogued as COSV100776062; called by muse, mutect2, varscan2
- CDH15 | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV99228732; called by muse, mutect2, varscan2
- CDR1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100983442; called by muse, mutect2, varscan2
- CENPE | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs760054720, COSV99478816; called by muse, mutect2, varscan2
- CEP128 | c.3094G>T p.G1032C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99825650; called by muse, mutect2, varscan2
- CERKL | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV100183435; called by mutect2, varscan2
- CES1 | c.1199C>T p.T400I (on ENST00000361503 / NM_001025194.2; = p.T399I on NM_001266.5) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100828773; called by muse, mutect2, varscan2
- CHD5 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99314644; called by muse, mutect2, varscan2
- CHD9 | c.3698G>C p.R1233T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99529588; called by muse, mutect2, varscan2
- CLEC16A | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV101278381; called by muse, mutect2, varscan2
- CLVS2 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773297906, COSV51560572; called by muse, mutect2, varscan2
- CNTNAP2 | c.1718G>T p.W573L | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100670010, COSV62159867; called by muse, mutect2, varscan2
- CNTNAP2 | c.1719G>T p.W573C | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100670013; called by muse, mutect2, varscan2
- CNTNAP4 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100272766; called by muse, mutect2, varscan2
- CNTROB | c.1981A>T p.T661S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100972747; called by muse, mutect2, varscan2
- COL11A2 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100554408; called by muse, mutect2, varscan2
- COL5A3 | c.3097G>A p.V1033I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs370189164; called by muse, varscan2
- CSMD2 | c.5827G>T p.G1943C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593918; called by muse, mutect2, varscan2
- CSMD2 | c.5827-1G>T p.X1943_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | catalogued as COSV99593932; called by muse, mutect2, varscan2
- CSMD2 | c.4864C>A p.Q1622K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV99593936; called by muse, mutect2, varscan2
- CSMD3 | c.3224G>A p.S1075N (on ENST00000297405 / NM_001363185.1; = p.S971N on NM_052900.3) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99843951; called by muse, mutect2, varscan2
- CTCF | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV99866296; called by muse, mutect2, varscan2
- CUX2 | c.1895A>T p.Q632L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99920457; called by muse, mutect2, varscan2
- CX3CL1 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99136465; called by muse, mutect2, varscan2
- CYP11B1 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV52827157, COSV99455544; called by muse, mutect2, varscan2
- DCDC1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs529307605, COSV100664013; called by muse, mutect2, varscan2
- DENND11 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV72097724; called by muse, mutect2, varscan2
- DENND1A | c.973A>T p.N325Y | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV101010768; called by muse, mutect2, varscan2
- DENND4A | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101475413; called by muse, mutect2, varscan2
- DIP2A | c.4075A>G p.M1359V | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV100596234; called by muse, mutect2, varscan2
- DMRT3 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51903643, COSV99506017; called by muse, mutect2, varscan2
- DNAH3 | c.8578C>T p.R2860W | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544228596, COSV99769821; called by muse, mutect2, varscan2
- DNAH7 | c.8747C>A p.A2916D | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56766049, COSV56771634; called by muse, mutect2, varscan2
- DNAH8 | c.6958T>C p.Y2320H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV100546761; called by muse, mutect2, varscan2
- DNAH9 | c.1424T>A p.L475Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318361237, COSV99303982; called by muse, mutect2, varscan2
- DNAJB7 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs201163369, COSV99344384; called by muse, mutect2, varscan2
- DOCK6 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV99626453; called by muse, mutect2, varscan2
- DST | c.1143A>G p.E381= | Splice Region (SNP) | VAF 47/108 reads (44%) | catalogued as COSV99758975; called by muse, mutect2, varscan2
- DYTN | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101510811, COSV101510895; called by muse, mutect2, varscan2
- EGFL8 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV100247063; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100349340; called by mutect2, varscan2
- ENAM | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV101253289; called by muse, mutect2, varscan2
- EPG5 | c.3942G>T p.K1314N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957880; called by muse, mutect2, varscan2
- EPHA7 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as COSV100994171; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | catalogued as rs771807343; called by mutect2, varscan2
- EPS15L1 | c.662G>C p.G221A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV99933542; called by muse, mutect2, varscan2
- EPS8 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as rs1457535054, COSV55528972; called by muse, mutect2, varscan2
- ERICH3 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV100445307; called by muse, mutect2, varscan2
- EVX2 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100420806, COSV57965545; called by muse, mutect2
- FAM120C | c.2486A>T p.D829V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100070388; called by muse, mutect2, varscan2
- FAM83F | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60999387, COSV61001016; called by muse, mutect2, varscan2
- FANCA | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101225132; called by muse, mutect2, varscan2
- FANCC | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.331); catalogued as COSV100002920; called by muse, mutect2, varscan2
- FARP2 | c.1961G>T p.C654F | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99885263; called by muse, mutect2, varscan2
- FBF1 | c.802G>C p.D268H (on ENST00000586717; = p.D282H on NM_001319193.1) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100045510; called by muse, varscan2
- FBLL1 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100606201; called by mutect2, varscan2
- FBN3 | c.3035C>A p.A1012D | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV99561013, COSV99561587; called by muse, mutect2, varscan2
- FLG2 | c.4845G>C p.E1615D | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV101166110, COSV66168124; called by muse, mutect2, varscan2
- FMN2 | c.4721A>C p.E1574A | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100146786; called by muse, mutect2, varscan2
- FRAS1 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV99355010; called by muse, mutect2, varscan2
- GALC | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs762593303, CM163002, COSV99730327; called by muse, mutect2, varscan2
- GALC | c.1793G>T p.W598L | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV99730330; called by muse, mutect2, varscan2
- GAS7 | c.649G>A p.V217M (on ENST00000432992 / NM_201433.2; = p.V77M on NM_003644.3) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs150413928; called by muse, mutect2, varscan2
- GFRA2 | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100152010; called by muse, mutect2, varscan2
- GJA10 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV101005424; called by muse, mutect2, varscan2
- GLDC | c.1737C>G p.I579M | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as COSV100394352, COSV100394458; called by muse, mutect2, varscan2
- GLDC | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100394461; called by muse, mutect2, varscan2
- GLIPR1L2 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100248718; called by muse, mutect2, varscan2
- GPR3 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100927538, COSV64994640; called by muse, mutect2, varscan2
- GPRC6A | c.1893A>T p.R631S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.079); catalogued as COSV100114646; called by muse, mutect2, varscan2
- GPRC6A | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV100114651; called by muse, mutect2, varscan2
- GRAP2 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703115; called by muse, mutect2, varscan2
- GRIN1 | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.97); catalogued as COSV100160619; called by muse, mutect2, varscan2
- GRTP1 | c.828G>C p.L276F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100208741; called by muse, mutect2, varscan2
- HAX1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as rs779012231, COSV99672021; called by muse, varscan2
- HBA2 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs281864887, COSV52406608, COSV99285422; called by muse, mutect2, varscan2
- HDAC4 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.342); catalogued as COSV100613534; called by muse, mutect2, varscan2
- HEATR5A | c.1493A>T p.H498L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101120425; called by muse, mutect2, varscan2
- HECW2 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99648428; called by muse, mutect2, varscan2
- HECW2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99648431; called by muse, mutect2, varscan2
- HOXB1 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53316388, COSV99495643; called by muse, mutect2, varscan2
- HSPB8 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.318); catalogued as COSV99931391; called by muse, mutect2, varscan2
- HTR5A | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as rs148427087; called by muse, mutect2, varscan2
- HYDIN | c.15145A>G p.M5049V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs768734492, COSV66638157; called by muse, mutect2, varscan2
- ICA1 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV99655714; called by muse, mutect2, varscan2
- ID4 | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1331033143, COSV101099555; called by muse, mutect2, varscan2
- IDO1 | c.696A>G p.I232M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs760305717, COSV99503561; called by muse, mutect2, varscan2
- IGHG2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as rs371694856; called by muse, mutect2, varscan2
- IGHV3-7 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.174); catalogued as rs576500777; called by muse, mutect2, varscan2
- IGLL1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.065); catalogued as COSV99968665; called by muse, mutect2, varscan2
- IGSF1 | c.2866C>A p.L956I | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.476); catalogued as rs201754584, COSV100811940; called by muse, mutect2, varscan2
- INHBE | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV56988215, COSV99875352; called by muse, mutect2, varscan2
- INPPL1 | c.2233C>G p.Q745E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV99996540; called by muse, mutect2, varscan2
- INSC | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.287); catalogued as rs1254586672, COSV101089547; called by muse, mutect2, varscan2
- INSRR | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV100947953; called by muse, mutect2, varscan2
- IQSEC2 | c.3332G>T p.G1111V (on ENST00000642864 / NM_001111125.3; = p.G906V on NM_015075.2) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.187); catalogued as COSV100945059; called by muse, mutect2, varscan2
- ISLR | c.806G>T p.W269L | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99997495; called by muse, mutect2, varscan2
- ITGAM | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99792948; called by muse, mutect2, varscan2
- ITGAX | c.248-2A>T p.X83_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99191966; called by muse, mutect2, varscan2
- ITGB4 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99564580; called by muse, mutect2, varscan2
- JAG2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.803); catalogued as rs761575707, COSV100078732; called by muse, mutect2, varscan2
- KCNG4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100377145, COSV57582702; called by muse, mutect2
- KCTD8 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100759955; called by muse, mutect2, varscan2
- KDM3B | c.3060G>A p.W1020* | Nonsense Mutation (SNP) | VAF 61/107 reads (57%) | catalogued as COSV100069500; called by muse, mutect2, varscan2
- KDM4C | c.2610G>T p.V870= | Splice Region (SNP) | VAF 20/42 reads (48%) | catalogued as COSV101185061, COSV67194088; called by muse, mutect2, varscan2
- KEAP1 | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99408155; called by muse, mutect2, varscan2
- KIF18B | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192497; called by muse, mutect2, varscan2
- KLC4 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs1438310233, COSV99432441; called by muse, mutect2, varscan2
- KLF7 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as COSV100519324, COSV58744828; called by muse, mutect2, varscan2
- KLHDC10 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV100111017; called by muse, mutect2, varscan2
- KMT2E | c.3236C>A p.S1079* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV57578777, COSV99996803, COSV99997164; called by muse, mutect2, varscan2
- KRT77 | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.487); catalogued as COSV100527221; called by muse, mutect2, varscan2
- KRT85 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99225654; called by muse, mutect2, varscan2
- KRTAP10-12 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV100554717, COSV100555019; called by muse, mutect2, varscan2
- KRTAP21-1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100624953; called by muse, mutect2, varscan2
- LCE4A | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated, low confidence (0.67); PolyPhen possibly damaging (0.648); catalogued as COSV100140093; called by muse, mutect2, varscan2
- LENG9 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV56617639; called by muse, mutect2, varscan2
- LILRB1 | c.592G>T p.D198Y (on ENST00000427581; = p.D162Y on NM_006669.6) | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100207692; called by muse, mutect2, varscan2
- LIN7A | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99692540; called by muse, mutect2, varscan2
- LINGO4 | c.1044C>A p.D348E | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV100765025; called by muse, mutect2, varscan2
- LMOD2 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101505464; called by muse, mutect2
- LRFN5 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV99985035; called by muse, mutect2, varscan2
- LRIT2 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100259296; called by muse, mutect2, varscan2
- LRP2 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55561555; called by muse, mutect2
- LRRC28 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100113788; called by muse, mutect2, varscan2
- LRRC30 | c.51G>T p.R17S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV101274444, COSV67301614; called by muse, mutect2, varscan2
- LRRC4 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV99975192; called by muse, mutect2, varscan2
- LRRC40 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs1292863232, COSV100918837; called by muse, mutect2, varscan2
- LRRC57 | c.222G>A p.L74= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as rs150825131, COSV52999316; called by muse, mutect2, varscan2
- LRRIQ3 | c.1584G>T p.L528F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV63040992; called by muse, mutect2, varscan2
- MACF1 | c.21116A>G p.K7039R (on ENST00000372915; = p.K5084R on NM_012090.5) | Missense Mutation (SNP) | VAF 57/191 reads (30%) | catalogued as COSV99246200; called by muse, mutect2, varscan2
- MAML2 | c.2661G>A p.M887I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV101594173; called by muse, mutect2, varscan2
- MAP3K19 | c.3118C>A p.L1040I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100209072; called by muse, mutect2, varscan2
- MAPK6 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1225886999, COSV99959355; called by muse, mutect2, varscan2
- MCL1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100329685; called by muse, mutect2, varscan2
- METTL17 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228326; called by muse, mutect2, varscan2
- MIB1 | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99839287; called by muse, mutect2, varscan2
- MKRN3 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.141); catalogued as COSV100091493, COSV58809083; called by muse, mutect2, varscan2
- MPEG1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV99915865; called by muse, mutect2, varscan2
- MPO | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV99832952; called by muse, mutect2, varscan2
- MPST | c.837G>C p.W279C (on ENST00000341116 / NM_001369904.2; = p.W299C on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100353427; called by muse, mutect2, varscan2
- MRGBP | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100978301; called by muse, mutect2, varscan2
- MS4A1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.436); catalogued as COSV100619412; called by muse, mutect2, varscan2
- MS4A14 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.394); catalogued as COSV100280678; called by muse, mutect2, varscan2
- MS4A14 | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.099); catalogued as COSV100280330; called by muse, mutect2
- MSTN | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs749046927, COSV99640804; called by muse, mutect2, varscan2
- MUC16 | c.28797G>T p.E9599D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as COSV101200949, COSV67501615; called by muse, mutect2, varscan2
- MUC16 | c.5331G>T p.M1777I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101200950; called by muse, mutect2, varscan2
- MUC3A | c.8873G>A p.C2958Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100115191; called by muse, mutect2, varscan2
- MYCT1 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100924087; called by muse, mutect2, varscan2
- MYH13 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52822437, COSV99355078, COSV99355676; called by muse, varscan2
- MYH7 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100806477; called by muse, mutect2, varscan2
- MYO15A | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765835381, COSV52751910; called by muse, mutect2, varscan2
- MYO1G | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349023; called by muse, mutect2, varscan2
- MYOM3 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100293587; called by muse, mutect2, varscan2
- MYPN | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100590432; called by muse, mutect2, varscan2
- MYT1L | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV101221238; called by muse, mutect2
- NANOG | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99981703; called by muse, mutect2, varscan2
- NAT10 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1565105246, COSV99140379; called by muse, mutect2, varscan2
- NAV2 | c.2044C>G p.Q682E (on ENST00000396087 / NM_001244963.2; = p.Q659E on NM_145117.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100586819; called by muse, mutect2, varscan2
- NCAPG2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99317498; called by muse, mutect2, varscan2
- NCBP3 | c.1770G>T p.Q590H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV99339669; called by muse, mutect2, varscan2
- NECTIN1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99872535; called by muse, mutect2, varscan2
- NEDD1 | c.562A>C p.T188P | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99901235; called by muse, mutect2, varscan2
- NLRC5 | c.4334G>A p.C1445Y | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.756); catalogued as COSV52661655; called by muse, mutect2, varscan2
- NMUR1 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs145120428; called by muse, mutect2, varscan2
- NPHS1 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100800186; called by muse, mutect2, varscan2
- NPY5R | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV58453231; called by muse, mutect2, varscan2
- NPY5R | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV100642890; called by muse, mutect2, varscan2
- NUBP1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV99296919; called by muse, mutect2, varscan2
- NUP155 | c.3245G>T p.W1082L (on ENST00000231498 / NM_153485.3; = p.W1023L on NM_004298.4) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194264; called by muse, mutect2, varscan2
- NUP50 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs761259920, COSV100754387; called by muse, mutect2, varscan2
- NXF3 | c.53G>C p.R18T | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV101222055, COSV67705500; called by muse, mutect2, varscan2
- OPCML | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV100103929; called by muse, mutect2, varscan2
- OR4B1 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.314); catalogued as COSV100535687; called by muse, mutect2, varscan2
- OR51Q1 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100333054; called by muse, mutect2, varscan2
- OR56B4 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV100337684, COSV57205246; called by muse, mutect2, varscan2
- OR5K3 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV67350418; called by muse, mutect2, varscan2
- OR5P2 | c.908G>C p.R303T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100271424, COSV61490295; called by muse, mutect2, varscan2
- OR8J1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV100275139; called by muse, mutect2, varscan2
- OSBP | c.1698C>G p.F566L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55665306, COSV99803299; called by muse, mutect2, varscan2
- OSBPL9 | c.1572G>C p.W524C | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100543960; called by muse, mutect2, varscan2
- OTOGL | c.3381C>G p.N1127K (on ENST00000547103; = p.N1118K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV101509472, COSV101509476; called by muse, mutect2, varscan2
- OTOP1 | c.1401C>G p.C467W | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV99587979; called by muse, mutect2
- OXR1 | c.1343C>G p.S448* (on ENST00000442977 / NM_001198532.1; = p.S447* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100367635; called by muse, mutect2, varscan2
- PADI1 | c.1276C>G p.P426A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969237; called by muse, mutect2
- PALM2AKAP2 | c.768del p.N257Tfs*24 (on ENST00000374531 / NM_001037293.2; = p.N289Tfs*24 on NM_053016.6) | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as COSV57116504; called by mutect2, pindel, varscan2
- PANX1 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV99921927, COSV99921975; called by muse, mutect2, varscan2
- PAPPA2 | c.1704C>A p.S568R | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100867013; called by muse, mutect2, varscan2
- PAPSS2 | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as COSV100753648; called by muse, mutect2, varscan2
- PCDH11Y | c.611G>A p.G204E (on ENST00000400457 / NM_032973.2; = p.G193E on NM_032971.3) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99292403; called by muse, mutect2, varscan2
- PCDH15 | c.2809C>A p.P937T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1463920111, COSV57256730; called by muse, mutect2
- PCDHB14 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.012); catalogued as COSV99506196; called by muse, mutect2
- PCDHB6 | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV99170735; called by muse, mutect2
- PCDHGA9 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV99544434; called by muse, mutect2
- PCSK2 | c.1907A>G p.N636S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99360413; called by muse, mutect2, varscan2
- PEAK1 | c.4715G>T p.R1572L | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100433353; called by muse, mutect2, varscan2
- PHKB | c.3203A>G p.Y1068C | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374634942; called by muse, mutect2, varscan2
- PIGR | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV100732594; called by muse, mutect2, varscan2
- PIK3CG | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV100783085; called by muse, mutect2, varscan2
- PIK3CG | c.2962A>C p.T988P | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100783086; called by muse, mutect2, varscan2
- PKN1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs781121850, COSV54396263; called by muse, mutect2, varscan2
- PKN3 | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV99403872; called by muse, mutect2, varscan2
- PLCB1 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100571837; called by muse, mutect2, varscan2
- PLEKHA8 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.613); catalogued as rs368054417; called by muse, mutect2, varscan2
- PLXNA4 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58169129; called by muse, mutect2, varscan2
- PNPT1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99570378; called by muse, varscan2
- POLD3 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.707); catalogued as COSV99738301; called by muse, mutect2, varscan2
- PPP1R12C | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV99670339; called by muse, mutect2, varscan2
- PPP3CB | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100646250; called by muse, mutect2, varscan2
- PRR16 | c.257G>A p.G86D (on ENST00000407149 / NM_001300783.2; = p.G63D on NM_016644.2) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV101087712; called by muse, mutect2, varscan2
- PRSS45P | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101374030; called by muse, mutect2, varscan2
- PSAP | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs1298247076, COSV101206515; called by muse, mutect2, varscan2
- PSD4 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1006612684, COSV99831396; called by muse, mutect2, varscan2
- PSMC3IP | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99519047; called by muse, mutect2, varscan2
- PSMC6 | c.344A>G p.D115G (on ENST00000612399; = p.D101G on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101471209; called by muse, mutect2, varscan2
- PSTK | c.656G>T p.W219L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100924790; called by muse, mutect2, varscan2
- PTPRT | c.2823C>G p.D941E | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100629627; called by muse, mutect2, varscan2
- PXDNL | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100685578; called by muse, mutect2, varscan2
- PYGO2 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as COSV100868979; called by muse, mutect2, varscan2
- RANGAP1 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100663816; called by muse, mutect2, varscan2
- RBBP6 | c.4011G>T p.Q1337H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs757556265, COSV60509383; called by muse, mutect2, varscan2
- RBM15 | c.2117G>T p.R706L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs1307680412, COSV63924363; called by muse, mutect2, varscan2
- RELN | c.4160G>C p.R1387P | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634332, COSV59020316; called by muse, mutect2, varscan2
- REN | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs544315427, COSV99689447, COSV99689712; called by muse, mutect2, varscan2
- RENBP | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892464, COSV64169402; called by muse, mutect2, varscan2
- REST | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.268); catalogued as COSV100471257; called by muse, mutect2, varscan2
- RFTN2 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV99695904; called by muse, mutect2, varscan2
- RGL1 | c.178C>T p.Q60* (on ENST00000360851 / NM_001297672.2; = p.Q95* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 116/268 reads (43%) | catalogued as COSV100487451; called by muse, mutect2, varscan2
- RNF152 | c.554T>A p.I185N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100455340; called by muse, mutect2, varscan2
- RORA | c.878A>G p.E293G (on ENST00000335670 / NM_134261.3; = p.E318G on NM_002943.3) | Missense Mutation (SNP) | VAF 93/185 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99832990; called by muse, mutect2, varscan2
- ROS1 | c.5906G>A p.G1969E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100877585; called by muse, mutect2, varscan2
- RP1L1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1260749096, COSV100261854, COSV100261918; called by muse, mutect2, varscan2
- RRAGA | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV100998156; called by muse, mutect2, varscan2
- RSPO1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV100740676; called by muse, mutect2, varscan2
- RTL9 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 88/145 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs199759157, COSV71826251; called by muse, mutect2, varscan2
- RUNDC3B | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV100407218; called by muse, mutect2, varscan2
- RYR2 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100769930, COSV100772199; called by muse, mutect2, varscan2
- RYR2 | c.12443T>A p.V4148D | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100772201; called by muse, mutect2, varscan2
- RYR2 | c.13819G>T p.A4607S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as HM030025, COSV100772204, COSV63664508; called by muse, mutect2
- SACS | c.13096G>T p.A4366S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV101207653; called by muse, mutect2, varscan2
- SACS | c.13095G>T p.Q4365H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV101207654; called by muse, mutect2, varscan2
- SAP30BP | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs769901204, COSV99503009; called by muse, mutect2, varscan2
- SCN1A | c.3120G>C p.R1040S (on ENST00000303395 / NM_001202435.3; = p.R1029S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV57676758, COSV57685117; called by muse, mutect2, varscan2
- SDAD1 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100668703; called by muse, mutect2, varscan2
- SDCCAG8 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV100654505; called by muse, mutect2, varscan2
- SEC23IP | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100957045; called by muse, mutect2, varscan2
- SERPINA11 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100594138; called by muse, mutect2, varscan2
- SHANK1 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99521801; called by muse, mutect2, varscan2
- SIGLEC12 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52460357, COSV99389543; called by muse, mutect2, varscan2
- SIGLEC6 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as COSV100585617; called by muse, mutect2, varscan2
- SIGLEC6 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58432434; called by muse, mutect2, varscan2
- SIGLEC9 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as COSV99143142; called by muse, mutect2, varscan2
- SLC10A2 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV99807653, COSV99808173; called by muse, mutect2, varscan2
- SLC14A2 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV99676005; called by muse, mutect2, varscan2
- SLC16A7 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99676785; called by muse, mutect2, varscan2
- SLC24A5 | c.1136C>A p.T379K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99982005; called by muse, mutect2, varscan2
- SLC26A5 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100099921; called by muse, mutect2, varscan2
- SLC44A5 | c.1963-1G>C p.X655_splice | Splice Site (SNP) | VAF 40/100 reads (40%) | catalogued as COSV100902412; called by muse, mutect2, varscan2
- SLC8A1 | c.1953A>T p.T651= | Splice Region (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100247106; called by muse, mutect2, varscan2
- SMAD1 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100129883; called by muse, mutect2
- SMC6 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as COSV100705324; called by muse, mutect2, varscan2
- SMYD3 | c.382G>A p.D128N (on ENST00000490107 / NM_001375962.1; = p.D69N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV101194369; called by muse, mutect2, varscan2
- SNX14 | c.1292T>C p.V431A (on ENST00000314673 / NM_001350535.1; = p.V387A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV100121731; called by muse, mutect2, varscan2
- SON | c.3968C>T p.S1323L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV99279452; called by muse, mutect2, varscan2
- SOX7 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs924751611, COSV58730900; called by muse, mutect2, varscan2
- SPTBN2 | c.3196C>T p.R1066W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1208354736, COSV100017916; called by muse, mutect2, varscan2
- SSMEM1 | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1420962974, COSV99927819; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 48/182 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV100084794; called by muse, mutect2, varscan2
- SULT1B1 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100150432; called by muse, mutect2
- SWT1 | c.827C>G p.S276* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV100833482; called by muse, mutect2, varscan2
- SYTL1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100539535; called by muse, mutect2, varscan2
- TAS2R41 | c.293G>T p.W98L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281511; called by muse, mutect2, varscan2
- TCP1 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as COSV100365032; called by muse, mutect2, varscan2
- TET3 | c.1838G>T p.R613M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs761657806, COSV99996551; called by muse, mutect2, varscan2
- TFEB | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100026398; called by muse, mutect2, varscan2
- TGIF2LY | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 91/126 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs779833813, COSV58291544; called by muse, mutect2, varscan2
- TIGD5 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99643623; called by muse, mutect2, varscan2
- TMBIM1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as COSV99298114; called by muse, mutect2
- TMEM255B | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100943275; called by muse, mutect2, varscan2
- TMPRSS11E | c.25A>T p.R9W | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.529); catalogued as COSV100542487; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4521G>C p.W1507C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100836193; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3419C>G p.S1140C | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV64100979; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2260C>G p.Q754E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV100836194; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100836195, COSV64101133; called by muse, mutect2, varscan2
- TNR | c.3983G>T p.G1328V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99690964; called by muse, mutect2, varscan2
- TRERF1 | c.1240A>T p.R414* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100551377; called by muse, mutect2, varscan2
- TRIM47 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs768531508, COSV99638634; called by muse, mutect2, varscan2
- TRIO | c.5678G>T p.R1893L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100710706, COSV100710802; called by muse, mutect2, varscan2
- TRRAP | c.11270G>A p.R3757Q (on ENST00000359863 / NM_001244580.1; = p.R3728Q on NM_003496.3) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs987263983, COSV100705480; called by muse, mutect2, varscan2
- TSNARE1 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs773450736, COSV100211242, COSV56185128; called by mutect2, varscan2
- TTC3 | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV100695915; called by muse, mutect2, varscan2
- TTLL5 | c.2197G>T p.V733L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100091271, COSV54029260; called by muse, mutect2, varscan2
- TTN | c.17584G>T p.E5862* (on ENST00000591111; = p.E4935* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/189 reads (35%) | catalogued as COSV100625182; called by muse, mutect2, varscan2
- TTN | c.17359C>A p.P5787T (on ENST00000591111; = p.P4860T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | PolyPhen possibly damaging (0.475); catalogued as COSV100625184; called by muse, mutect2
- TUT4 | c.2791G>T p.D931Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99932686; called by muse, mutect2, varscan2
- TWNK | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV61327665; called by muse, mutect2, varscan2
- TXLNB | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100625131; called by muse, mutect2, varscan2
- UBC | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100299091; called by muse, mutect2, varscan2
- UBQLN3 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293909; called by muse, mutect2
- UBR4 | c.5611G>C p.E1871Q | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100921500; called by muse, mutect2, varscan2
- UGT1A10 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.125); catalogued as COSV100762232; called by muse, mutect2, varscan2
- USH2A | c.7325G>A p.R2442K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV100240406; called by muse, mutect2, varscan2
- USH2A | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240411; called by muse, mutect2, varscan2
- USP32 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100342648; called by muse, mutect2, varscan2
- VAV3 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100580239; called by muse, mutect2, varscan2
- VGF | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); catalogued as rs1189784296, COSV99973152; called by muse, mutect2, varscan2
- VIP | c.88A>G p.R30G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100923960; called by muse, mutect2, varscan2
- VWF | c.5348C>T p.S1783L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99779866; called by muse, mutect2, varscan2
- WDPCP | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99706451; called by muse, mutect2, varscan2
- WDR59 | c.741T>A p.N247K | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.197); catalogued as COSV100049628; called by muse, mutect2, varscan2
- WSCD2 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54578076, COSV99775082; called by muse, mutect2, varscan2
- XIRP2 | c.865G>T p.V289L (on ENST00000628543; = p.V464L on NM_152381.6) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99746261; called by muse, mutect2, varscan2
- ZEB2 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV100355536, COSV100356637; called by muse, mutect2, varscan2
- ZFP57 | c.1029C>A p.N343K | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100971940, COSV65305856; called by muse, mutect2, varscan2
- ZMIZ1 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100566451; called by muse, mutect2, varscan2
- ZNF239 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100021876; called by muse, mutect2, varscan2
- ZNF28 | c.1649C>A p.P550Q | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100354572, COSV100354657; called by muse, mutect2, varscan2
- ZNF318 | c.3809C>T p.S1270L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1292342861, COSV100546438; called by muse, mutect2, varscan2
- ZNF415 | c.1543C>A p.Q515K | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV99701880; called by muse, mutect2, varscan2
- ZNF45 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV99524233; called by muse, mutect2, varscan2
- ZNF519 | c.1496G>T p.R499M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV101645588; called by muse, mutect2, varscan2
- ZNF521 | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100833103; called by muse, mutect2, varscan2
- ZNF527 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100648765; called by muse, mutect2, varscan2
- ZNF536 | c.2261C>G p.P754R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100835665; called by muse, mutect2, varscan2
- ZNF560 | c.2235T>A p.C745* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100038914; called by muse, mutect2, varscan2
- ZNF639 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 57/132 reads (43%) | catalogued as COSV100418473; called by muse, mutect2, varscan2
- ZNF648 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as COSV100374727; called by muse, mutect2, varscan2
- ZNF770 | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100696028; called by muse, mutect2, varscan2
- ZNF80 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100352108; called by muse, mutect2, varscan2
- ZNF84 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1469230430; called by muse, mutect2, varscan2
- ZXDB | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.171); catalogued as COSV100886016; called by muse, mutect2
- ZYX | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1436350308, COSV100503807; called by muse, mutect2, varscan2
- ACSM4 | c.59del p.G20Afs*14 | Frame Shift Del (DEL) | VAF 90/260 reads (35%) | called by mutect2, pindel, varscan2
- AHCYL2 | c.1809del p.F604Sfs*12 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- CCKAR | c.1193del p.G398Efs*24 | Frame Shift Del (DEL) | VAF 41/99 reads (41%) | called by mutect2, pindel, varscan2
- DRP2 | c.270_271del p.H91Qfs*25 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by pindel, varscan2
- GGNBP2 | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- HADH | c.926_942del p.G309Vfs*13 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | called by mutect2, pindel, varscan2
- HMCES | c.484_486delinsAA p.E162Kfs*13 | Frame Shift Del (DEL) | VAF 39/161 reads (24%) | called by pindel, varscan2*
- KIF13A | c.1746dup p.A583Cfs*12 | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | called by mutect2, pindel, varscan2
- KLHL30 | c.510_517del p.F171Afs*34 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.246del p.T83Hfs*32 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- MCHR1 | c.1179_1189del p.S394Cfs*16 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- MN1 | c.3200del p.Q1067Rfs*3 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- OR8G2P | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, varscan2
- PDLIM1 | c.586del p.V196Ffs*11 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- PPAT | c.566dup p.M189Ifs*28 | Frame Shift Ins (INS) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- RYR2 | c.8935C>T p.R2979C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- S100A12 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A11 | c.565_567del p.H189del | In Frame Del (DEL) | VAF 46/175 reads (26%) | called by mutect2, pindel, varscan2
- SUCLA2 | c.1043dup p.L348Ffs*21 (on ENST00000643023; = p.L327Ffs*21 on NM_003850.3) | Frame Shift Ins (INS) | VAF 43/109 reads (39%) | called by mutect2, pindel, varscan2
- TRGV4 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WDFY3 | c.9015dup p.D3006Rfs*25 | Frame Shift Ins (INS) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- ZAN | c.7008_7009insA p.P2337Tfs*7 | Frame Shift Ins (INS) | VAF 24/38 reads (63%) | called by mutect2, varscan2
- ZBTB32 | c.27del p.S10Afs*11 | Frame Shift Del (DEL) | VAF 126/316 reads (40%) | called by mutect2, pindel, varscan2
- ABCC8 | c.669T>C p.N223= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100217615; called by muse, mutect2, varscan2
- ABCG8 | c.609C>A p.T203= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs1268619474, COSV55396055; called by muse, mutect2, varscan2
- ACTC1 | c.972T>C p.P324= | Silent (SNP) | VAF 92/298 reads (31%) | catalogued as COSV99292068; called by muse, mutect2, varscan2
- ADCY6 | c.471G>C p.A157= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100326810; called by muse, mutect2, varscan2
- AICDA | c.219C>A p.G73= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV99984329; called by muse, mutect2, varscan2
- ALDH5A1 | c.657G>T p.L219= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as COSV100708893; called by muse, mutect2, varscan2
- AMER3 | c.12G>A p.K4= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs766452593, COSV100366515, COSV100366802; called by muse, mutect2, varscan2
- ANKRD1 | c.918C>G p.L306= | Silent (SNP) | VAF 72/254 reads (28%) | catalogued as rs761447714, COSV100865359, COSV65467909; called by muse, mutect2, varscan2
- ARMH4 | c.1455C>G p.L485= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs140880514, COSV50780374; called by muse, mutect2, varscan2
- ATP6V0D1 | c.318C>T p.I106= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs747420026, COSV52097095; called by muse, mutect2, varscan2
- ATRNL1 | c.543T>A p.V181= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100746732; called by muse, mutect2, varscan2
- BLM | c.2253C>T p.L751= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100757295; called by muse, mutect2, varscan2
- CCNT1 | c.1431A>G p.P477= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV99980872; called by muse, mutect2, varscan2
- CDH9 | c.1083G>A p.L361= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99151250, COSV99162626; called by muse, mutect2, varscan2
- CHAF1A | c.1743C>T p.I581= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs888321623, COSV100011393; called by muse, mutect2, varscan2
- CHST6 | c.474C>T p.F158= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV100178571; called by muse, mutect2, varscan2
- CLCNKA | c.756C>T p.L252= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as COSV100510291; called by muse, mutect2, varscan2
- CLRN2 | c.654C>A p.T218= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV101492697; called by muse, mutect2, varscan2
- CNKSR1 | c.870C>T p.P290= (on ENST00000374253 / NM_001297647.2; = p.P283= on NM_006314.3) | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as rs1346593758, COSV100836769; called by muse, mutect2, varscan2
- COLGALT2 | c.1880G>A p.*627= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100730820; called by muse, mutect2, varscan2
- CST11 | c.255G>C p.L85= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100983582; called by muse, mutect2
- DDX39B | c.834C>G p.L278= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100795264; called by muse, mutect2, varscan2
- DOCK6 | c.297C>T p.I99= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53924813; called by muse, mutect2, varscan2
- DPP10 | c.1401A>T p.S467= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV100070466; called by muse, mutect2, varscan2
- ECT2L | c.216G>A p.V72= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100872145; called by muse, mutect2, varscan2
- EHMT2 | c.2757G>A p.E919= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100977234; called by muse, mutect2, varscan2
- EMILIN3 | c.1756C>T p.L586= | Silent (SNP) | VAF 66/195 reads (34%) | catalogued as COSV100182768; called by muse, mutect2, varscan2
- ETF1 | c.1032C>T p.L344= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV100860249; called by muse, mutect2, varscan2
- FAM163B | c.201C>A p.T67= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- FAM47A | c.1263G>C p.V421= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100649680, COSV100650019; called by muse, mutect2, varscan2
- FGD2 | c.495C>T p.F165= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99236531; called by muse, mutect2, varscan2
- FGF11 | c.138G>A p.L46= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99548479; called by muse, mutect2, varscan2
- FUT4 | c.138G>A p.A46= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100708161; called by muse, mutect2, varscan2
- FXR2 | c.435G>A p.E145= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100007278; called by muse, mutect2, varscan2
- GANC | c.2523G>C p.L841= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV100531151, COSV58807423; called by muse, mutect2, varscan2
- GBX1 | c.801A>G p.A267= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99881010; called by muse, mutect2, varscan2
- GDF3 | c.627T>C p.D209= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs764686808, COSV100325324; called by muse, mutect2, varscan2
- GLIPR1L2 | c.192G>T p.L64= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100158115; called by muse, mutect2, varscan2
- GOLGA6B | c.1179G>A p.E393= | Silent (SNP) | VAF 9/33 reads (27%) | called by mutect2, varscan2
- GPRC5B | c.114G>A p.G38= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100315259, COSV56027533; called by muse, mutect2, varscan2
- GRAP2 | c.414C>A p.S138= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100703117; called by muse, mutect2, varscan2
- GRIK1 | c.1335C>A p.A445= | Silent (SNP) | VAF 67/224 reads (30%) | catalogued as COSV100413267; called by muse, mutect2, varscan2
- GTF2F1 | c.1110C>G p.P370= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101081143, COSV101081366; called by muse, mutect2
- IGDCC4 | c.1809T>G p.A603= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100733099; called by muse, mutect2, varscan2
- IL23R | c.1141C>A p.R381= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100724642; called by muse, mutect2, varscan2
- IRF2BP1 | c.996G>A p.E332= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs746945912, COSV100138977; called by muse, mutect2, varscan2
- ITGAM | c.1797G>A p.L599= (on ENST00000648685 / NM_001145808.2; = p.L598= on NM_000632.4) | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV99792951; called by muse, mutect2, varscan2
- KCNMB3 | c.447G>A p.Q149= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV99842004; called by muse, mutect2, varscan2
- KCNU1 | c.3058C>A p.R1020= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV101299402, COSV67755610; called by muse, mutect2, varscan2
- KLK4 | c.429C>A p.T143= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs767967124, COSV100133579, COSV100133691; called by muse, mutect2, varscan2
- KRT20 | c.486G>A p.E162= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as rs767085035, COSV99391548; called by muse, mutect2, varscan2
- KRT23 | c.534C>T p.L178= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV99266329; called by muse, mutect2, varscan2
- LRFN2 | c.48C>A p.A16= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs370059282, COSV100599833; called by muse, mutect2, varscan2
- MAP3K5 | c.4023C>G p.L1341= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV100753163; called by muse, mutect2, varscan2
- MCTP1 | c.1104T>C p.P368= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100387872; called by muse, mutect2, varscan2
- MED13L | c.2871G>T p.P957= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV56119539, COSV99929835; called by muse, mutect2, varscan2
- MORC1 | c.1980G>T p.L660= | Silent (SNP) | VAF 58/94 reads (62%) | catalogued as rs748443685, COSV99227350; called by muse, mutect2, varscan2
- MPO | c.1473C>A p.A491= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as COSV99832951; called by muse, mutect2, varscan2
- MROH2B | c.1155C>T p.S385= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV101270868; called by muse, mutect2, varscan2
- MUC3A | c.8079T>A p.S2693= | Silent (SNP) | VAF 172/1090 reads (16%) | catalogued as COSV100115184; called by muse, mutect2, varscan2
- MYOM3 | c.3172C>A p.R1058= | Silent (SNP) | VAF 168/359 reads (47%) | catalogued as rs374495623; called by muse, mutect2, varscan2
- NF1 | c.426A>G p.L142= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as CD000947, COSV100647976; called by muse, mutect2, varscan2
- NFE2L3 | c.1686C>T p.F562= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99283947, COSV99283962; called by muse, mutect2, varscan2
- NMUR1 | c.1230C>T p.P410= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100532102; called by muse, varscan2
- NOL6 | c.546G>C p.L182= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99955077; called by muse, mutect2, varscan2
- NR1H3 | c.1216C>A p.R406= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV100211867; called by muse, mutect2, varscan2
- NTRK1 | c.1716C>T p.I572= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs759767777, COSV62328128; called by muse, mutect2, varscan2
- OAS3 | c.759A>G p.R253= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99966493; called by muse, mutect2, varscan2
- OR10J3 | c.720C>T p.A240= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100171845; called by muse, mutect2, varscan2
- OR2T27 | c.849C>A p.P283= | Silent (SNP) | VAF 43/63 reads (68%) | catalogued as COSV100788304; called by muse, mutect2, varscan2
- OR8K1 | c.114C>T p.L38= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV54405117; called by muse, mutect2, varscan2
- PADI6 | c.1128C>T p.I376= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100639999; called by muse, mutect2, varscan2
- PATJ | c.753C>T p.L251= | Silent (SNP) | VAF 109/251 reads (43%) | catalogued as rs1297192844, COSV100334773; called by muse, mutect2, varscan2
- PCDH7 | c.2613G>T p.L871= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- PFKM | c.2211C>T p.P737= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1165739164, COSV100402661; called by muse, mutect2, varscan2
- PIK3CD | c.1071G>A p.T357= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs1038371431, COSV100740411; called by muse, mutect2, varscan2
- PKN1 | c.1017C>T p.T339= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99661685; called by muse, mutect2, varscan2
- PKN1 | c.1261C>T p.L421= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99661687; called by muse, mutect2, varscan2
- PKN1 | c.1482C>T p.F494= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV99660895; called by muse, varscan2
- PLB1 | c.48G>T p.L16= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100579686; called by muse, mutect2, varscan2
- PLCG1 | c.1122G>C p.G374= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99719159; called by muse, mutect2, varscan2
- PMS1 | c.1521A>C p.S507= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100575754; called by muse, mutect2, varscan2
- PNLDC1 | c.1020G>A p.E340= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99277765; called by muse, mutect2, varscan2
- POLR3E | c.1821A>G p.L607= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs753590590, COSV100242315; called by muse, mutect2, varscan2
- PPT2 | c.879T>C p.Y293= | Silent (SNP) | VAF 77/258 reads (30%) | catalogued as COSV100247062; called by muse, mutect2, varscan2
- PRKAG3 | c.237G>C p.R79= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV99292087; called by muse, mutect2, varscan2
- RAB12 | c.174G>C p.L58= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs201144141, COSV61399262; called by muse, mutect2, varscan2
- RANBP17 | c.354G>T p.G118= | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as COSV101206364; called by muse, mutect2, varscan2
- RPN2 | c.1215A>G p.T405= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99411973; called by muse, mutect2, varscan2
- RPS4Y2 | c.447C>T p.Y149= | Silent (SNP) | VAF 125/151 reads (83%) | catalogued as COSV99978428; called by muse, mutect2, varscan2
- RPS6KB2 | c.1035C>T p.F345= | Silent (SNP) | VAF 127/436 reads (29%) | catalogued as COSV100396707; called by muse, mutect2, varscan2
- S100A12 | c.231G>A p.L77= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV100907176; called by muse, mutect2, varscan2
- SBF1 | c.3585C>T p.V1195= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs777461626, COSV100817973; called by muse, mutect2, varscan2
- SENP6 | c.372G>T p.T124= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100519480; called by muse, mutect2
- SH3PXD2A | c.1956G>C p.L652= (on ENST00000369774 / NM_001365079.1; = p.L624= on NM_014631.2) | Silent (SNP) | VAF 56/215 reads (26%) | catalogued as COSV100280390; called by muse, mutect2, varscan2
- SIGLEC12 | c.231C>A p.A77= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV52462412; called by muse, mutect2, varscan2
- SIRPB1 | c.1080C>A p.T360= | Silent (SNP) | VAF 90/223 reads (40%) | catalogued as COSV99498529; called by muse, mutect2
- SLC6A19 | c.375G>A p.V125= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100443397; called by muse, mutect2, varscan2
- SLC9B1 | c.1437C>A p.I479= | Silent (SNP) | VAF 32/410 reads (8%) | catalogued as COSV56470284, COSV99600011; called by muse, mutect2
- SLC9C2 | c.2275C>T p.L759= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV100876948; called by muse, mutect2, varscan2
- SMYD5 | c.1131C>T p.S377= | Silent (SNP) | VAF 45/192 reads (23%) | catalogued as COSV99240331; called by muse, mutect2, varscan2
- SOCS5 | c.135C>T p.I45= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100125422; called by muse, mutect2, varscan2
- SYNE3 | c.2529G>A p.S843= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs540053794, COSV100515883; called by muse, mutect2, varscan2
- TACC2 | c.8187C>T p.I2729= (on ENST00000334433; = p.I807= on NM_006997.4) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs762408075, COSV53291738; called by muse, mutect2, varscan2
- TMEM63B | c.484C>T p.L162= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99441985; called by muse, mutect2, varscan2
- TRGV4 | c.219C>T p.S73= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as rs766636019; called by muse, mutect2, varscan2
- TTC8 | c.339C>G p.L113= (on ENST00000338104 / NM_001288781.1; = p.L123= on NM_144596.4) | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV100581606; called by muse, mutect2, varscan2
- TTLL10 | c.1296G>A p.L432= (on ENST00000379289 / NM_001130045.2; = p.L359= on NM_153254.3) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101016856; called by muse, mutect2, varscan2
- TTN | c.67815T>A p.P22605= (on ENST00000591111; = p.P15181= on NM_003319.4) | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100625175; called by muse, mutect2, varscan2
- TTN | c.9885G>C p.T3295= (on ENST00000591111; = p.T3249= on NM_003319.4) | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV100625186, COSV59891992; called by muse, mutect2, varscan2
- TTN | c.7818G>A p.A2606= (on ENST00000591111; = p.A2560= on NM_003319.4) | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs935809232, COSV60131234; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TXNDC16 | c.291G>A p.K97= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99909550; called by muse, mutect2, varscan2
- UNC13A | c.1410G>A p.E470= | Silent (SNP) | VAF 122/266 reads (46%) | catalogued as COSV53209230; called by muse, mutect2, varscan2
- UNC13C | c.795G>A p.G265= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99521792; called by muse, mutect2, varscan2
- VN1R5 | c.51A>T p.S17= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs749643966; called by muse, mutect2, varscan2
- WWC3 | c.2520C>T p.I840= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs947994175, COSV101081688; called by muse, mutect2, varscan2
- ZBED1 | c.1101G>A p.Q367= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100585965; called by muse, mutect2, varscan2
- ZBTB24 | c.297C>A p.L99= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100018680; called by muse, mutect2, varscan2
- ZNF280A | c.1002C>A p.T334= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV100131203; called by muse, mutect2, varscan2
- ZNF512 | c.72G>A p.R24= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100820931; called by muse, mutect2, varscan2
- ZSWIM8 | c.3969G>A p.L1323= (on ENST00000605216 / NM_001242487.2; = p.L1328= on NM_015037.3) | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs754207199, COSV100014287; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208236 T>A | 5'Flank (SNP) | VAF 47/125 reads (38%) | called by muse, mutect2, varscan2
- DDX41 | c.*634G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as COSV57251271; called by muse, mutect2, varscan2
- GAD2 | c.-1G>C | 5'UTR (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99392778, COSV99393847; called by muse, varscan2
- MIR1-1HG-AS1 | n.883C>T | RNA (SNP) | VAF 32/87 reads (37%) | catalogued as rs1555901792; called by muse, mutect2, varscan2
- MYH6 | c.4175+198G>T | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100676897; called by muse, mutect2, varscan2
- NCR3 | c.-1C>A | 5'UTR (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99279184; called by muse, mutect2, varscan2
- NDUFA10 | c.999+6482G>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99401672; called by muse, mutect2, varscan2
- PAK6 | c.-117-664C>T | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99544896; called by muse, mutect2, varscan2
- POM121C | chr7:75416124 T>C | 3'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163923 G>T | 5'Flank (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- RPL31P57 | n.104G>T | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- SSPOP | n.15584G>T | RNA (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100947899; called by muse, mutect2, varscan2
- TEX101 | c.-12C>A | 5'UTR (SNP) | VAF 171/354 reads (48%) | catalogued as COSV99494931; called by muse, mutect2, varscan2
- TEX2 | chr17:64146341 G>A | 3'Flank (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- TMTC2 | c.*2A>G | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100338675; called by muse, mutect2, varscan2
